Somatic mutation profile of tumor specimen TCGA-86-6851-01A (aliquot TCGA-86-6851-01A-11D-1945-08) from TCGA case TCGA-86-6851, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.4 years (26,808 days).
Specimen TCGA-86-6851-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f880828-1f81-4973-8efa-a052497c2b0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-6851-10A (Blood Derived Normal), aliquot TCGA-86-6851-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ae532c3-6923-4272-8286-97ace9db9437

The open-access MAF lists 948 somatic variants for this specimen: 737 protein-altering or splice-affecting, 187 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 636, Silent 187, Nonsense Mutation 47, Splice Site 21, Frame Shift Del 21, RNA 8, Intron 7, Frame Shift Ins 7, 3'Flank 4, Translation Start Site 3, 5'UTR 2, 5'Flank 2.

Variants (750 of 948; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV52517971, COSV52518546; called by muse, mutect2, varscan2
- TP53 | c.774A>T p.E258D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52752502, COSV52980614; called by muse, mutect2, varscan2
- AADACL4 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66105774, COSV66106316; called by muse, mutect2, varscan2
- AASDH | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52706751; called by muse, mutect2, varscan2
- AASDH | c.872C>T p.T291I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52706766; called by muse, mutect2, varscan2
- ABCA10 | c.1286A>C p.N429T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV52222397; called by muse, mutect2, varscan2
- ABCA9 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100382713, COSV60625057; called by muse, mutect2, varscan2
- ABCC2 | c.1154G>T p.C385F | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64970923; called by muse, mutect2
- ABHD16A | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65451834; called by muse, mutect2, varscan2
- AC004593.2 | c.887C>A p.T296K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56092507, COSV99765489; called by muse, mutect2, varscan2
- ACP7 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58699362; called by muse, mutect2, varscan2
- ACSBG1 | c.427C>A p.R143S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV51906319; called by muse, mutect2, varscan2
- ACSM2B | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409204223, COSV61657955; called by muse, mutect2
- ACTB | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as rs1484491064, COSV59318696, COSV59320746; called by muse, mutect2
- ACVRL1 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as CD159688, COSV66360238; called by muse, mutect2, varscan2
- ADAM19 | c.1353G>T p.R451S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV57430367; called by muse, mutect2, varscan2
- ADAM21 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV50794053; called by muse, mutect2, varscan2
- ADAM30 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV65561133; called by muse, mutect2, varscan2
- ADAMTS12 | c.3997_3998insA p.A1333Dfs*15 | Frame Shift Ins (INS) | VAF 10/94 reads (11%) | catalogued as COSV100710134; called by pindel, varscan2
- ADAMTS12 | c.838G>T p.G280W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61259397, COSV61263423; called by muse, mutect2, varscan2
- ADAMTS19 | c.2973G>C p.W991C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV50749056, COSV50772259; called by muse, mutect2, varscan2
- ADAMTS20 | c.2674C>A p.L892I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as COSV67131842; called by muse, varscan2
- ADAMTS7 | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV66307350; called by muse, mutect2, varscan2
- ADAMTSL1 | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV52816053; called by muse, mutect2, varscan2
- ADCY1 | c.1148+1G>T p.X383_splice | Splice Site (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52033392, COSV52034912; called by muse, mutect2, varscan2
- ADCY2 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV57873615; called by muse, varscan2
- ADCY8 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53908407; called by muse, mutect2, varscan2
- ADGRG7 | c.1724G>T p.W575L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56296862; called by muse, mutect2, varscan2
- ADGRL3 | c.1382C>T p.P461L (on ENST00000506720 / NM_001322402.2; = p.P393L on NM_015236.6) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV72268487; called by muse, mutect2, varscan2
- ADRA1B | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60701843; called by muse, mutect2, varscan2
- AFM | c.1688A>T p.D563V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs1436122549, COSV56920194; called by muse, mutect2, varscan2
- AHNAK | c.8773G>T p.V2925F | Missense Mutation (SNP) | VAF 82/336 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV57214226; called by muse, mutect2, varscan2
- AHRR | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57086494; called by muse, mutect2, varscan2
- AHSG | c.548A>T p.E183V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56607848; called by muse, mutect2, varscan2
- AKAP12 | c.4472C>T p.T1491I | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs749656784, COSV53575436; called by muse, mutect2, varscan2
- AKR1B1 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53647354; called by muse, mutect2
- ALDH1B1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.909); catalogued as COSV66619750; called by muse, mutect2, varscan2
- ANKS3 | c.1845G>C p.M615I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV58509034; called by muse, mutect2
- ANKS4B | c.582C>A p.F194L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs376304434, COSV61139275; called by muse, mutect2, varscan2
- ANO3 | c.1891T>A p.S631T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.305); catalogued as COSV99879984; called by muse, mutect2, varscan2
- ANO4 | c.175A>G p.N59D (on ENST00000392977 / NM_001286615.2; = p.N24D on NM_178826.4) | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen possibly damaging (0.899); catalogued as COSV54596420; called by muse, mutect2, varscan2
- ANO4 | c.2324A>T p.E775V (on ENST00000392977 / NM_001286615.2; = p.E740V on NM_178826.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV54596434; called by muse, mutect2, varscan2
- ANXA6 | c.1871G>C p.R624T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62906796; called by mutect2, varscan2
- AP3M1 | c.1256del p.*419= | Frame Shift Del (DEL) | VAF 31/104 reads (30%) | catalogued as COSV53012774; called by mutect2, pindel, varscan2
- AP4M1 | c.542A>T p.Q181L | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV57996564; called by muse, mutect2, varscan2
- APOA1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as COSV52635780; called by muse, mutect2, varscan2
- APOB | c.1637A>T p.Q546L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV51936095; called by muse, mutect2, varscan2
- AQP1 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762474222, COSV61266734; called by muse, mutect2, varscan2
- AQP7 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV53015799; called by muse, mutect2, varscan2
- AR | c.2256G>C p.W752C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM993917, COSV65954676, COSV65957258; called by muse, mutect2, varscan2
- ARAP2 | c.1532G>T p.S511I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV100394002; called by muse, mutect2, varscan2
- ARID2 | c.2302G>T p.V768L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57604242; called by muse, mutect2, varscan2
- ARMC4 | c.2834C>G p.A945G | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59463954; called by muse, mutect2, varscan2
- ARMCX2 | c.1886T>C p.V629A | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57530146; called by muse, mutect2, varscan2
- ASAP2 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55631966; called by muse, mutect2, varscan2
- ASB15 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV51926061; called by muse, mutect2, varscan2
- ASCC3 | c.6275G>T p.G2092V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100976164; called by muse, mutect2, varscan2
- ASCC3 | c.6274G>T p.G2092W | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100976165; called by muse, mutect2, varscan2
- ASIC4 | c.1217C>G p.S406C (on ENST00000347842 / NM_182847.3; = p.S425C on NM_018674.6) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV61731880; called by muse, mutect2
- ASIC5 | c.945C>A p.C315* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV73332744; called by muse, mutect2, varscan2
- ASTL | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV60904278; called by muse, mutect2, varscan2
- ATP11A | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV52112098; called by muse, mutect2, varscan2
- ATP1A4 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.747); catalogued as COSV63626573; called by muse, mutect2, varscan2
- ATP2A2 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58042903; called by muse, mutect2, varscan2
- ATP5MF | c.17A>T p.E6V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.661); catalogued as COSV52854733; called by muse, mutect2, varscan2
- ATP8A1 | c.2236G>T p.G746W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52535519; called by muse, mutect2, varscan2
- ATP9A | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58766787; called by muse, varscan2
- B2M | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV62564183; called by muse, mutect2, varscan2
- BCAS1 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV65086115; called by muse, mutect2
- BCAS1 | c.479A>C p.Q160P | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.131); catalogued as COSV65086129; called by muse, mutect2
- BPIFA1 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as rs765317724, COSV62824032; called by muse, mutect2, varscan2
- BRINP2 | c.137A>T p.H46L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.107); catalogued as COSV64177600; called by muse, mutect2, varscan2
- BRINP3 | c.651C>A p.C217* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV66517506; called by muse, mutect2, varscan2
- BTNL2 | c.1144T>C p.S382P | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV66630763; called by muse, mutect2, varscan2
- BUB1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs1322086360, COSV57063748; called by muse, mutect2, varscan2
- BVES | c.677G>T p.R226I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV58947985; called by muse, mutect2, varscan2
- BZW2 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.441); catalogued as COSV51755180; called by muse, mutect2, varscan2
- C11orf71 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1051890, COSV100348338, COSV57784357; called by muse, mutect2, varscan2
- C12orf66 | c.1127A>G p.N376S | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.03); catalogued as COSV61323244; called by muse, mutect2, varscan2
- C2CD3 | c.3824A>G p.H1275R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58093305; called by muse, mutect2, varscan2
- CAB39L | c.267A>G p.I89M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV61715011; called by muse, mutect2, varscan2
- CACNA1E | c.5077C>T p.R1693C | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs745342948, COSV62396016; called by muse, varscan2
- CACNA1E | c.5092C>A p.L1698M | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV62396039; called by muse, varscan2
- CACNG7 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.173); catalogued as COSV55814536; called by muse, mutect2, varscan2
- CACUL1 | c.949G>T p.V317L | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs377310953, COSV60994499; called by muse, mutect2, varscan2
- CADPS2 | c.3512G>A p.G1171E | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV57364327; called by muse, mutect2
- CALU | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV50821814; called by muse, varscan2
- CAMTA1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770043613, COSV57902122; called by muse, mutect2, varscan2
- CAPN11 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV67237622; called by muse, mutect2, varscan2
- CAPN6 | c.1648G>T p.V550F | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60695097; called by muse, mutect2, varscan2
- CAPRIN2 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as COSV51832653, COSV51834406; called by muse, mutect2, varscan2
- CASP5 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.149); catalogued as COSV52828707; called by muse, mutect2, varscan2
- CBLN2 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV54051265; called by muse, mutect2, varscan2
- CBWD1 | c.242-2A>G p.X81_splice | Splice Site (SNP) | VAF 33/85 reads (39%) | catalogued as COSV100070552; called by mutect2, varscan2
- CCDC70 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs759430954, COSV54430233; called by mutect2, varscan2
- CCDC80 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 39/157 reads (25%) | catalogued as COSV52817000; called by muse, mutect2, varscan2
- CCDC83 | c.1099C>A p.P367T (on ENST00000342404 / NM_001286159.2; = p.P398T on NM_173556.5) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1292288432, COSV54699938, COSV54701528, COSV54701944; called by muse, mutect2, varscan2
- CCER1 | c.1050C>A p.N350K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as rs954408670, COSV62646928; called by muse, mutect2, varscan2
- CCNE1 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52904498; called by muse, mutect2, varscan2
- CCSER1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1215145266, COSV61432014; called by muse, mutect2
- CCT8 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV54504083; called by muse, mutect2
- CD300LB | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV58725748; called by muse, mutect2, varscan2
- CDC34 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV53116615, COSV53116797; called by muse, mutect2, varscan2
- CDH12 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV66405981, COSV66444693; called by muse, mutect2, varscan2
- CDH17 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.52); catalogued as COSV50328778; called by muse, mutect2, varscan2
- CDHR1 | c.2237C>G p.P746R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.215); catalogued as COSV60562499; called by muse, mutect2, varscan2
- CDSN | c.1458T>A p.C486* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV52538185; called by muse, mutect2, varscan2
- CDX1 | c.677C>A p.P226Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV51568406; called by muse, mutect2, varscan2
- CDYL | c.1450G>T p.G484C (on ENST00000328908 / NM_001368125.1; = p.G430C on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59359759; called by muse, mutect2, varscan2
- CEACAM18 | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.176); catalogued as COSV67282991; called by muse, mutect2, varscan2
- CEACAM4 | c.423C>A p.H141Q | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV55731751; called by muse, mutect2, varscan2
- CEP152 | c.3418G>T p.G1140* | Nonsense Mutation (SNP) | VAF 26/140 reads (19%) | catalogued as COSV57859617; called by muse, mutect2, varscan2
- CEP164 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV54041521; called by muse, mutect2
- CEP164 | c.2822G>C p.R941T | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV54041537; called by muse, mutect2, varscan2
- CEP44 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.875); catalogued as COSV56659348; called by muse, mutect2, varscan2
- CERS3 | c.326C>G p.T109R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52568776; called by muse, mutect2, varscan2
- CFHR3 | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66402219; called by muse, varscan2
- CHRM3 | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99697271; called by muse, mutect2, varscan2
- CHRM3 | c.1682G>T p.C561F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55089607, COSV55109205; called by muse, mutect2, varscan2
- CHRNA7 | c.1149C>G p.N383K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs752404462, COSV100181725; called by mutect2, varscan2
- CHRNB3 | c.1327G>T p.V443F | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); catalogued as COSV51497371, COSV99250806; called by muse, mutect2, varscan2
- CLCA2 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV65286907, COSV65287247; called by muse, mutect2, varscan2
- CLCNKA | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV58891676; called by muse, mutect2, varscan2
- CLIP2 | c.2072A>T p.E691V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.638); catalogued as COSV56278919; called by muse, mutect2
- CLTCL1 | c.4393G>C p.E1465Q | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54231328; called by muse, mutect2
- CLVS2 | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.395); catalogued as COSV51563047; called by muse, mutect2, varscan2
- CNPPD1 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV55407392; called by muse, mutect2, varscan2
- CNTNAP5 | c.1576A>T p.I526F | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV101443368, COSV70486883; called by muse, mutect2, varscan2
- COL11A1 | c.2723G>T p.G908V | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV62184069; called by muse, mutect2, varscan2
- COL14A1 | c.5005G>A p.G1669S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52854924, COSV52865980; called by muse, mutect2, varscan2
- COL19A1 | c.590C>A p.T197N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV59573836, COSV59594374; called by muse, mutect2, varscan2
- COL24A1 | c.3736-1G>T p.X1246_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV65306649; called by muse, mutect2, varscan2
- COL24A1 | c.2311-1G>T p.X771_splice | Splice Site (SNP) | VAF 12/78 reads (15%) | catalogued as COSV65306653; called by muse, varscan2
- COL25A1 | c.413-1G>T p.X138_splice | Splice Site (SNP) | VAF 36/102 reads (35%) | catalogued as COSV101211091; called by muse, mutect2, varscan2
- COL6A3 | c.27A>T p.L9F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV55090294; called by muse, mutect2, varscan2
- COL9A3 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59652934; called by muse, mutect2, varscan2
- COLEC11 | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV52597210, COSV99362748; called by muse, mutect2, varscan2
- COLEC11 | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV52591943, COSV52598549, COSV99362752; called by muse, mutect2, varscan2
- COLEC12 | c.2155G>T p.D719Y | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141957359, COSV68370718; called by muse, mutect2, varscan2
- CPEB1 | c.622C>A p.P208T (on ENST00000617958; = p.P148T on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as rs1198907027, COSV55619021; called by muse, mutect2, varscan2
- CPQ | c.882G>T p.W294C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55146249; called by muse, mutect2, varscan2
- CPS1 | c.3774G>T p.L1258F | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51810777; called by muse, mutect2, varscan2
- CSH2 | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs184890744, COSV61081151; called by muse, mutect2, varscan2
- CSMD2 | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53914110; called by muse, mutect2, varscan2
- CSMD3 | c.4689G>C p.E1563D (on ENST00000297405 / NM_001363185.1; = p.E1459D on NM_052900.3) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV52185806; called by muse, mutect2, varscan2
- CSMD3 | c.2606G>T p.G869V (on ENST00000297405 / NM_001363185.1; = p.G765V on NM_052900.3) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52185822, COSV99826995; called by muse, mutect2, varscan2
- CSMD3 | c.2604G>T p.Q868H (on ENST00000297405 / NM_001363185.1; = p.Q764H on NM_052900.3) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV52185841; called by muse, mutect2
- CSNK1E | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100725101, COSV63291034; called by muse, mutect2, varscan2
- CSPG4 | c.2482G>C p.A828P | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57895362; called by muse, mutect2, varscan2
- CTAGE1 | c.1045C>A p.Q349K | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV66943481; called by muse, varscan2
- CTCFL | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.321); catalogued as COSV54774573; called by muse, mutect2, varscan2
- CTNNA2 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63568809; called by muse, mutect2, varscan2
- CTSF | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV59748752; called by muse, mutect2, varscan2
- CTTN | c.88-1G>C p.X30_splice | Splice Site (SNP) | VAF 21/118 reads (18%) | catalogued as COSV57232538; called by muse, mutect2, varscan2
- CUL1 | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV57388771; called by muse, mutect2, varscan2
- CUL1 | c.1643A>C p.Q548P | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as COSV57388777; called by muse, mutect2, varscan2
- CUL4A | c.958G>T p.A320S (on ENST00000375440 / NM_001008895.4; = p.A220S on NM_003589.3) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58373038; called by muse, mutect2, varscan2
- CXADR | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53029157; called by muse, mutect2
- D2HGDH | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs149383887, COSV58320896; called by muse, mutect2, varscan2
- DBX1 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV57054111; called by muse, mutect2, varscan2
- DCAF4L2 | c.1106C>A p.S369Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV60478868, COSV60479047; called by muse, mutect2, varscan2
- DCAKD | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as COSV60202327; called by muse, mutect2, varscan2
- DCT | c.111C>A p.N37K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV65469193; called by muse, mutect2, varscan2
- DCTN1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV62620520; called by muse, mutect2, varscan2
- DEFB110 | c.167G>T p.C56F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV64484517; called by muse, mutect2, varscan2
- DEFB121 | c.130T>C p.C44R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773974946, COSV66236276; called by muse, mutect2, varscan2
- DENND5A | c.3647del p.G1216Afs*38 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs1564877269, CM125351; called by mutect2, pindel, varscan2
- DGKK | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65707574; called by muse, mutect2, varscan2
- DIO3 | c.634T>A p.S212T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV63773743; called by muse, mutect2, varscan2
- DLX5 | c.158del p.G53Efs*28 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | catalogued as COSV56034256; called by mutect2, pindel, varscan2
- DMXL1 | c.8740G>C p.D2914H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60711945; called by muse, mutect2, varscan2
- DNAH10 | c.9130G>T p.A3044S (on ENST00000409039; = p.A2983S on NM_207437.3) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV68994184; called by muse, mutect2, varscan2
- DNAH11 | c.5531G>A p.C1844Y | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60956462, COSV60975963; called by muse, mutect2, varscan2
- DNAH17 | c.1156A>T p.T386S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67754721; called by mutect2, varscan2
- DNAH5 | c.9960G>A p.M3320I | Missense Mutation (SNP) | VAF 141/248 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV54225911; called by muse, mutect2, varscan2
- DNAH5 | c.3317A>G p.Y1106C | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV54225922; called by muse, mutect2, varscan2
- DNAI3 | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV54002680; called by muse, mutect2, varscan2
- DPP8 | c.2398G>T p.D800Y (on ENST00000341861 / NM_001320875.2; = p.D684Y on NM_017743.6) | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV55678859; called by muse, mutect2, varscan2
- DPY19L4 | c.2007+1G>T p.X669_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as COSV68962916; called by muse, mutect2, varscan2
- DST | c.1883G>T p.G628V (on ENST00000361203 / NM_001374722.1; = p.G302V on NM_001723.6) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55015660; called by muse, mutect2, varscan2
- DTNA | c.1714C>A p.P572T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV52004282; called by muse, varscan2
- ECT2 | c.440G>C p.R147T (on ENST00000392692 / NM_001349098.2; = p.R116T on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV51689024; called by muse, mutect2
- EEF1A2 | c.773-1G>A p.X258_splice | Splice Site (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99418960; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1244A>T p.E415V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV62567993; called by muse, mutect2
- EHMT1 | c.961C>G p.H321D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); catalogued as COSV58375259; called by muse, varscan2
- EID3 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61599043; called by muse, mutect2, varscan2
- EIF2B3 | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV100838982, COSV64517479; called by muse, mutect2, varscan2
- ELAVL4 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100836481; called by muse, mutect2, varscan2
- ELAVL4 | c.824C>A p.P275Q | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100836483; called by muse, mutect2, varscan2
- ELSPBP1 | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.237); catalogued as rs1222264508, COSV60413752; called by muse, mutect2, varscan2
- EML4 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV59298332; called by muse, mutect2, varscan2
- ENTHD1 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57320397; called by muse, mutect2, varscan2
- EPHA5 | c.834del p.E279Kfs*143 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as COSV56637499; called by mutect2, varscan2
- EPHA6 | c.2971G>T p.A991S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs1210768152, COSV67572717; called by muse, mutect2, varscan2
- EPHB1 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.28); catalogued as rs373296912, COSV67661955; called by mutect2, varscan2
- EPRS1 | c.3613G>T p.V1205F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65099178; called by muse, mutect2, varscan2
- EPRS1 | c.2969C>G p.S990C | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV65099186, COSV65099226; called by muse, mutect2, varscan2
- ERICH6 | c.1630C>A p.R544S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs373184930, COSV55800578; called by muse, mutect2, varscan2
- ERP44 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52431845; called by muse, mutect2, varscan2
- ESRP1 | c.1693G>C p.V565L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV64409915; called by muse, mutect2, varscan2
- EXOC5 | c.887G>T p.R296M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV61770803; called by muse, mutect2, varscan2
- EYS | c.129G>T p.W43C | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV60986017; called by muse, mutect2, varscan2
- F13A1 | c.1908+1G>A p.X636_splice | Splice Site (SNP) | VAF 15/77 reads (19%) | catalogued as COSV53558752; called by muse, mutect2, varscan2
- F13B | c.1178A>G p.N393S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV66373935; called by muse, mutect2, varscan2
- F5 | c.4174C>T p.P1392S | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs768300712, COSV63124205; called by muse, mutect2, varscan2
- F5 | c.898G>T p.V300L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV63124214; called by muse, mutect2, varscan2
- F7 | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV60646118; called by muse, mutect2, varscan2
- F7 | c.994A>T p.T332S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV60646128; called by muse, mutect2, varscan2
- FAM135B | c.3625A>T p.I1209L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.844); catalogued as COSV52726200; called by muse, mutect2, varscan2
- FAM13C | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV53248713; called by muse, mutect2
- FAM214A | c.3011G>C p.R1004T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV55924268; called by muse, mutect2, varscan2
- FAM47C | c.297G>C p.K99N | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV63726702; called by muse, mutect2, varscan2
- FAM47C | c.1008G>T p.K336N | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as COSV63726709; called by muse, mutect2, varscan2
- FAM83B | c.2867C>A p.T956N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV60920838, COSV60922242; called by muse, mutect2, varscan2
- FANCD2OS | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55038133; called by muse, mutect2, varscan2
- FAT3 | c.4075C>G p.P1359A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV53113253; called by muse, mutect2, varscan2
- FAT3 | c.12192C>G p.C4064W | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53113271; called by muse, mutect2, varscan2
- FAXC | c.1001G>T p.W334L | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67602220; called by muse, mutect2, varscan2
- FBLN1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs974015899, COSV53047439; called by muse, mutect2, varscan2
- FBN2 | c.7547C>T p.S2516L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs797045574, COSV52514438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN3 | c.4175G>T p.G1392V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54461460; called by muse, mutect2, varscan2
- FBXL20 | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52899175, COSV99233920; called by muse, varscan2
- FCRL1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV63825287; called by muse, mutect2, varscan2
- FER | c.118A>T p.K40* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV55291656; called by muse, mutect2, varscan2
- FER1L6 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67550028; called by muse, mutect2, varscan2
- FER1L6 | c.3175C>A p.P1059T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67550031, COSV67551003; called by muse, mutect2, varscan2
- FGD1 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV64308747; called by muse, mutect2, varscan2
- FHL5 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.405); catalogued as COSV58737609; called by muse, mutect2, varscan2
- FHOD1 | c.2928C>G p.F976L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV50760948; called by muse, mutect2, varscan2
- FHOD3 | c.2180A>C p.Q727P (on ENST00000359247 / NM_001281739.3; = p.Q744P on NM_025135.5) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99939813; called by mutect2, varscan2
- FIG4 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV57787730; called by muse, mutect2, varscan2
- FMN2 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60431117; called by muse, mutect2, varscan2
- FNDC3B | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61042577; called by muse, mutect2, varscan2
- FOLH1 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs778134535, COSV57046475, COSV57049371; called by muse, mutect2, varscan2
- FOXD3 | c.495C>G p.S165R | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100942882, COSV64379986; called by muse, mutect2, varscan2
- FURIN | c.1484A>G p.Y495C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51576874; called by muse, mutect2, varscan2
- FUT7 | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV55801681; called by muse, mutect2, varscan2
- GABRB1 | c.1326C>A p.D442E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as COSV54982226; called by muse, mutect2, varscan2
- GABRR1 | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); catalogued as COSV65619446; called by muse, mutect2, varscan2
- GALC | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV54324476, COSV54325729; called by muse, mutect2
- GALNT14 | c.1262A>T p.K421M | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.852); catalogued as COSV61105373; called by muse, mutect2, varscan2
- GANC | c.651C>G p.F217L | Missense Mutation (SNP) | VAF 31/160 reads (19%) | PolyPhen benign (0.047); catalogued as COSV58809081; called by muse, mutect2, varscan2
- GBP6 | c.1274G>T p.S425I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV65011514; called by muse, mutect2, varscan2
- GCNT2 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as COSV65457349; called by muse, mutect2, varscan2
- GDF5 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65501661; called by muse, mutect2, varscan2
- GLI3 | c.1952C>A p.P651Q | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV67888744; called by muse, mutect2, varscan2
- GLIS2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1043516792, COSV52110687; called by muse, mutect2, varscan2
- GLT1D1 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV55882228; called by muse, mutect2
- GNAS | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM163149, COSV99668869; called by muse, mutect2, varscan2
- GOLGA6B | c.1037T>A p.L346H | Missense Mutation (SNP) | VAF 87/495 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV69770150; called by muse, mutect2, varscan2
- GPC5 | c.1360G>T p.V454L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as COSV65599829; called by muse, mutect2, varscan2
- GPNMB | c.1687C>A p.L563I (on ENST00000381990 / NM_001005340.2; = p.L551I on NM_002510.3) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51698563; called by muse, mutect2, varscan2
- GPR158 | c.1946C>A p.A649E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV66270634; called by muse, mutect2, varscan2
- GPR173 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100212279, COSV60234943; called by muse, mutect2, varscan2
- GPR183 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs200952492, COSV63118088; called by muse, mutect2, varscan2
- GPR37 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58256952; called by muse, mutect2
- GPR55 | c.349A>C p.M117L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67407751; called by muse, mutect2, varscan2
- GPR75 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV61827682; called by muse, mutect2, varscan2
- GRIN2A | c.3154C>A p.L1052I | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV58033914, COSV58050799, COSV58061393; called by muse, mutect2, varscan2
- GRIN2B | c.3383G>T p.G1128V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.499); catalogued as COSV74205985; called by muse, mutect2, varscan2
- GRIN2B | c.3208T>A p.Y1070N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV74205986; called by muse, mutect2, varscan2
- GRM1 | c.1747G>C p.V583L | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV51151630; called by muse, mutect2, varscan2
- GRM7 | c.878+1G>T p.X293_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as COSV63143863; called by muse, mutect2, varscan2
- GTF2I | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60401359; called by muse, mutect2
- GZMA | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.54); catalogued as rs1165866044, COSV57113218; called by muse, mutect2, varscan2
- H1-5 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58900104; called by muse, mutect2, varscan2
- H2BW1 | c.266T>A p.L89Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54220298; called by muse, mutect2, varscan2
- H3C6 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV64519609, COSV64519990; called by muse, mutect2, varscan2
- HACE1 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs763431334, COSV53502606; called by muse, mutect2, varscan2
- HAVCR2 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); catalogued as COSV100324577; called by muse, varscan2
- HCK | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52942788; called by muse, mutect2, varscan2
- HCLS1 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV58856605; called by muse, mutect2, varscan2
- HCN1 | c.2353C>A p.P785T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.058); catalogued as COSV57511193; called by muse, mutect2, varscan2
- HCRTR2 | c.889C>G p.R297G | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as COSV63795955, COSV63799577; called by muse, mutect2, varscan2
- HDLBP | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs1392123829, COSV100190133, COSV60495928; called by muse, mutect2, varscan2
- HECA | c.1519G>T p.G507W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100866139, COSV62769921; called by muse, mutect2, varscan2
- HERC1 | c.8719A>T p.S2907C | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.343); catalogued as COSV71247895; called by muse, mutect2, varscan2
- HEXA | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV51506542; called by muse, mutect2, varscan2
- HGF | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as COSV55948083, COSV55949917, COSV55959244; called by muse, mutect2, varscan2
- HIVEP2 | c.3580G>C p.E1194Q | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.143); catalogued as COSV50014055; called by muse, mutect2, varscan2
- HIVEP2 | c.2668G>C p.E890Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50014104, COSV99174680; called by muse, mutect2, varscan2
- HIVEP3 | c.1802A>G p.Y601C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1418001949, COSV56015745; called by muse, mutect2, varscan2
- HKDC1 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV63577236; called by muse, mutect2, varscan2
- HMCN1 | c.10391C>G p.A3464G | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.209); catalogued as COSV54901796; called by muse, mutect2, varscan2
- HNF4A | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57380846, COSV57383100; called by muse, mutect2
- HOXA5 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV56073142; called by muse, mutect2, varscan2
- HOXD1 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV100514300, COSV58923549; called by muse, mutect2, varscan2
- HP1BP3 | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV56562665; called by muse, mutect2, varscan2
- HRNR | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs774271387, COSV64258155; called by muse, mutect2, varscan2
- HSD3B2 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1248063754, COSV65593201; called by muse, mutect2, varscan2
- HSPB2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV57051725; called by muse, mutect2, varscan2
- HTR1E | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.972); catalogued as COSV59508243; called by muse, varscan2
- HTR1E | c.1025T>A p.L342Q | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59508248; called by muse, varscan2
- IGF1R | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV51289456; called by muse, mutect2, varscan2
- IGFBP3 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.021); catalogued as rs781717855, COSV51872442; called by muse, mutect2, varscan2
- IGHV1-2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1212150223; called by muse, mutect2, varscan2
- IGKV1D-16 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs774987960; called by muse, mutect2, varscan2
- IGLV5-37 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1436075428; called by muse, mutect2, varscan2
- IGSF22 | c.1152C>A p.H384Q | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60034362; called by muse, mutect2, varscan2
- IKBKB | c.1836C>G p.L612= | Splice Region (SNP) | VAF 7/60 reads (12%) | catalogued as rs946523062, COSV60596975; called by muse, mutect2, varscan2
- IL1B | c.552C>A p.Y184* | Nonsense Mutation (SNP) | VAF 47/183 reads (26%) | catalogued as COSV54521724; called by muse, mutect2, varscan2
- IL37 | c.585C>G p.N195K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54491169, COSV54494205; called by mutect2, varscan2
- IMPDH1 | c.1514T>G p.L505R (on ENST00000470772 / NM_001142573.2; = p.L591R on NM_000883.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV58316108; called by muse, mutect2, varscan2
- INHBA | c.242C>A p.A81E | Missense Mutation (SNP) | VAF 124/468 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54219478, COSV54221719; called by muse, mutect2, varscan2
- ITGA6 | c.2162C>A p.P721H (on ENST00000442250; = p.P682H on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51225279; called by muse, mutect2
- ITGA8 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | catalogued as COSV65229107; called by muse, mutect2
- ITGB6 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51794111; called by muse, mutect2
- ITGB8 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV56008976; called by muse, mutect2
- ITIH2 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64433283; called by muse, mutect2, varscan2
- ITIH2 | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64433286; called by muse, mutect2, varscan2
- ITSN2 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.396); catalogued as COSV61947603; called by muse, mutect2, varscan2
- JARID2 | c.719A>T p.K240I | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV59189575; called by muse, mutect2, varscan2
- JCAD | c.31C>A p.H11N | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64759725; called by muse, mutect2, varscan2
- KBTBD7 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV65266428; called by muse, mutect2, varscan2
- KCNB2 | c.176C>A p.T59K | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV73048998, COSV73050348; called by muse, mutect2, varscan2
- KCNG1 | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV65368495, COSV65369121; called by muse, mutect2, varscan2
- KCNH8 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 50/162 reads (31%) | catalogued as COSV60459063, COSV60464216; called by muse, mutect2, varscan2
- KCNJ1 | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs779487505, COSV60661857; called by muse, mutect2, varscan2
- KCNJ5 | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); catalogued as rs863224689, COSV57966219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD2 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV100483197; called by muse, mutect2
- KDM3B | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.028); catalogued as COSV58690859; called by muse, mutect2, varscan2
- KIAA0930 | c.864C>A p.F288L (on ENST00000336156 / NM_001009880.2; = p.F293L on NM_015264.2) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV52662054, COSV52663368; called by muse, mutect2, varscan2
- KIF13A | c.1150G>C p.A384P | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52451685, COSV99435471; called by muse, mutect2, varscan2
- KIF17 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV56118319; called by mutect2, varscan2
- KIF3B | c.1003A>T p.N335Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65227645; called by muse, mutect2, varscan2
- KIF6 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as rs909413439, COSV99756705; called by muse, mutect2, varscan2
- KIR2DL4 | c.304T>C p.Y102H (on ENST00000396284; = p.Y63H on NM_001080770.2) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.567); catalogued as COSV100610708, COSV60878723; called by muse, mutect2, varscan2
- KLHL41 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52930310; called by muse, mutect2, varscan2
- KMT2E | c.2726C>G p.S909C | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV57572845, COSV57573521; called by muse, mutect2
- KRT36 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV60203441; called by muse, mutect2, varscan2
- KRT85 | c.629+1G>A p.X210_splice | Splice Site (SNP) | VAF 23/133 reads (17%) | catalogued as COSV57736942; called by muse, mutect2, varscan2
- KSR2 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779409612, COSV56673016; called by muse, mutect2, varscan2
- LAMB4 | c.4153G>T p.V1385L | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as rs1393675929, COSV52719860; called by muse, mutect2, varscan2
- LAS1L | c.2051G>T p.R684L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as COSV56707405; called by muse, mutect2, varscan2
- LILRA2 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1410613346, COSV52191992; called by muse, varscan2
- LILRB2 | c.532C>A p.R178S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV58744033, COSV58745403; called by muse, varscan2
- LIMD1 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 24/103 reads (23%) | catalogued as COSV56267427; called by muse, mutect2, varscan2
- LIPF | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV53284084; called by muse, mutect2, varscan2
- LIPG | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54296355; called by muse, mutect2, varscan2
- LIPH | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56184063; called by muse, mutect2, varscan2
- LMO7 | c.1972G>A p.E658K (on ENST00000357063; = p.E388K on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV58536873; called by muse, mutect2, varscan2
- LMTK2 | c.427A>T p.I143F | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51996127; called by muse, mutect2, varscan2
- LRFN5 | c.583C>A p.H195N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV53256913; called by muse, mutect2, varscan2
- LRP1B | c.2059C>A p.Q687K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.012); catalogued as COSV67222019; called by muse, mutect2, varscan2
- LRP2 | c.8396T>A p.I2799N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV55554118; called by muse, mutect2, varscan2
- LRP2 | c.4763T>A p.M1588K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.084); catalogued as COSV55554129; called by muse, mutect2, varscan2
- LRRC28 | c.806A>G p.H269R | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57338280; called by muse, mutect2, varscan2
- LRRC31 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV52981078; called by muse, mutect2, varscan2
- LRRC43 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60290061; called by muse, mutect2, varscan2
- LRRC49 | c.1856A>G p.E619G | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53010976; called by muse, mutect2, varscan2
- LRRC4C | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV53426265; called by muse, mutect2, varscan2
- LRRC4C | c.954C>A p.D318E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53426285; called by muse, mutect2, varscan2
- LRRC8C | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64998088; called by muse, mutect2, varscan2
- LRRK2 | c.2290A>T p.S764C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV54153952; called by muse, mutect2, varscan2
- LRRN2 | c.85T>A p.C29S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65783853; called by muse, mutect2, varscan2
- LRRN3 | c.921C>A p.N307K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1316180174, COSV100066469; called by muse, mutect2
- LRRN3 | c.922C>A p.L308M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100066473; called by muse, mutect2
- LRRTM4 | c.1614C>A p.C538* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV69162753; called by muse, mutect2, varscan2
- LTBP1 | c.1288T>A p.C430S (on ENST00000404816 / NM_206943.4; = p.C104S on NM_000627.4) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV63187423; called by muse, mutect2, varscan2
- LTBP1 | c.2548C>A p.P850T (on ENST00000404816 / NM_206943.4; = p.P524T on NM_000627.4) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63187438, COSV63195405; called by muse, mutect2, varscan2
- MAGEB4 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66775758, COSV66775982; called by muse, mutect2, varscan2
- MAGI1 | c.803T>A p.L268* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100439007, COSV58322538; called by muse, mutect2, varscan2
- MALT1 | c.2159G>T p.G720V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV61934959; called by muse, mutect2, varscan2
- MAP3K20 | c.2257G>T p.D753Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV100919360, COSV64380309; called by muse, mutect2, varscan2
- MARCHF11 | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV60128740; called by muse, mutect2, varscan2
- MATN2 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV54711516; called by muse, mutect2, varscan2
- MB21D2 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV66663612; called by muse, mutect2, varscan2
- MC2R | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV59618218; called by muse, varscan2
- MDH1 | c.676-1G>C p.X226_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV51863597; called by muse, mutect2
- MEAF6 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56163577; called by muse, mutect2, varscan2
- MGAT5 | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV56096604; called by muse, mutect2, varscan2
- MIA2 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV54483626; called by muse, varscan2
- MIB2 | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as COSV61542701; called by muse, mutect2, varscan2
- MICAL3 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); catalogued as rs368481659; called by muse, mutect2, varscan2
- MKI67 | c.5336G>T p.G1779V | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64074464; called by muse, mutect2, varscan2
- MMP15 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs749513199, COSV54679857; called by muse, mutect2, varscan2
- MOAP1 | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); catalogued as COSV52092586; called by muse, varscan2
- MORN1 | c.449+1G>T p.X150_splice | Splice Site (SNP) | VAF 20/84 reads (24%) | catalogued as COSV58100842; called by muse, mutect2, varscan2
- MPP3 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs910532990, COSV68198215; called by muse, mutect2
- MRGPRD | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV58423181; called by muse, mutect2, varscan2
- MROH2B | c.1204C>A p.Q402K | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV68184412; called by muse, mutect2, varscan2
- MSN | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV64304086; called by muse, mutect2, varscan2
- MTA1 | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58757417; called by muse, mutect2, varscan2
- MTA1 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495385, COSV58757425; called by muse, mutect2, varscan2
- MTIF2 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55051660; called by muse, mutect2
- MUC21 | c.1617G>T p.R539S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as rs1034839897, COSV66220877; called by muse, mutect2, varscan2
- MUC5B | c.14414C>G p.S4805C | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV71592125, COSV71593128, COSV71594342; called by muse, mutect2
- MUTYH | c.380-1G>T p.X127_splice | Splice Site (SNP) | VAF 16/86 reads (19%) | catalogued as CS031780, CS042821, COSV58344158; called by muse, mutect2, varscan2
- MXRA5 | c.3757T>A p.S1253T | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54235729; called by muse, mutect2, varscan2
- MYCT1 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65891347; called by muse, mutect2, varscan2
- MYH1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 42/152 reads (28%) | catalogued as COSV55437388, COSV55438734; called by muse, mutect2, varscan2
- MYLK2 | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV65659097; called by muse, mutect2
- MYO18B | c.7608C>A p.D2536E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.086); catalogued as COSV59134870; called by muse, mutect2, varscan2
- MYO5B | c.872G>C p.G291A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53219220; called by muse, mutect2, varscan2
- MYRIP | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV56869523; called by muse, mutect2, varscan2
- MYT1L | c.1377G>T p.R459S | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV67715847, COSV67720720; called by mutect2, varscan2
- NAP1L2 | c.756T>A p.D252E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV65172524; called by muse, mutect2
- NAV2 | c.6224T>C p.L2075P (on ENST00000396087 / NM_001244963.2; = p.L2016P on NM_145117.5) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60659535; called by muse, mutect2, varscan2
- NAV3 | c.4759A>G p.T1587A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.993); catalogued as COSV57081073; called by muse, mutect2, varscan2
- NCOA1 | c.2697A>G p.I899M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV56044514; called by muse, mutect2, varscan2
- NCOA2 | c.2016G>T p.L672F | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as COSV71764001; called by muse, mutect2, varscan2
- NCR1 | c.648C>G p.N216K | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.444); catalogued as COSV52556713; called by muse, mutect2, varscan2
- NDNF | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV65633526; called by muse, mutect2, varscan2
- NDRG3 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as COSV62422008; called by muse, mutect2, varscan2
- NDST1 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55787420; called by muse, mutect2, varscan2
- NECTIN1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.875); catalogued as COSV50599872; called by muse, mutect2, varscan2
- NEIL3 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as COSV52810554; called by muse, mutect2, varscan2
- NELFB | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58025035; called by muse, mutect2
- NEXMIF | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV50032327; called by muse, mutect2, varscan2
- NFASC | c.1499C>A p.T500N (on ENST00000339876 / NM_001378329.1; = p.T511N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs1281353967, COSV58365906; called by muse, mutect2, varscan2
- NFATC3 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60473812; called by muse, mutect2, varscan2
- NGB | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV53611443; called by muse, mutect2, varscan2
- NID2 | c.311C>A p.P104Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV53496667; called by muse, mutect2, varscan2
- NLRP13 | c.2468C>A p.S823* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV61621787; called by muse, mutect2, varscan2
- NLRP8 | c.2881G>T p.E961* | Nonsense Mutation (SNP) | VAF 11/99 reads (11%) | catalogued as COSV52583592, COSV52587481; called by muse, mutect2, varscan2
- NOTCH2 | c.6552G>T p.L2184F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.289); catalogued as COSV99862425; called by muse, mutect2, varscan2
- NOTCH4 | c.2438+2T>A p.X813_splice | Splice Site (SNP) | VAF 5/44 reads (11%) | catalogued as COSV66680793; called by muse, mutect2, varscan2
- NR6A1 | c.700G>C p.G234R (on ENST00000487099 / NM_033334.4; = p.G229R on NM_001489.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV60633413; called by muse, mutect2, varscan2
- NRAP | c.4164C>A p.F1388L (on ENST00000359988 / NM_001322945.2; = p.F1353L on NM_006175.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1054038086, COSV63490752; called by muse, mutect2, varscan2
- NRIP3 | c.235G>C p.G79R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.12); catalogued as COSV58469863; called by muse, mutect2, varscan2
- NRROS | c.233A>T p.Q78L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60746014; called by muse, mutect2, varscan2
- NRXN1 | c.3541C>A p.H1181N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs377333818; called by muse, mutect2, varscan2
- NRXN1 | c.1389G>T p.M463I | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.045); catalogued as COSV58448995, COSV58454175; called by muse, mutect2, varscan2
- NRXN3 | c.3035G>T p.R1012L (on ENST00000335750 / NM_001330195.2; = p.R639L on NM_004796.6) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59750874; called by muse, mutect2, varscan2
- NSMAF | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV50687338, COSV99232546; called by muse, varscan2
- NTRK3 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV58123133, COSV58128117; called by muse, mutect2, varscan2
- NXF5 | n.412-2A>T | Splice Site (SNP) | VAF 38/101 reads (38%) | catalogued as COSV53791162; called by muse, mutect2, varscan2
- NYAP1 | c.2411G>T p.C804F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV55718934; called by muse, mutect2, varscan2
- OCRL | c.628T>C p.F210L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV63980937; called by muse, mutect2, varscan2
- OFD1 | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV60796027; called by muse, mutect2, varscan2
- OLFM4 | c.685T>A p.S229T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV54577510; called by muse, mutect2, varscan2
- OR10A6 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs749670272, COSV59165154, COSV59165396; called by muse, mutect2, varscan2
- OR10T2 | c.415A>C p.K139Q | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV57781459; called by muse, mutect2, varscan2
- OR1E1 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV59459021; called by muse, mutect2, varscan2
- OR1N2 | c.863T>A p.L288Q | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1320906734, COSV65460655; called by muse, mutect2, varscan2
- OR2T12 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV58777573; called by muse, mutect2, varscan2
- OR2T2 | c.260T>A p.L87Q | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV61618150; called by muse, mutect2
- OR2T27 | c.369C>A p.Y123* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV61282211; called by muse, mutect2, varscan2
- OR4A15 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs149233751, COSV59033784, COSV59035376; called by muse, varscan2
- OR4A16 | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as COSV59043201; called by muse, mutect2, varscan2
- OR4D6 | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV55659830; called by muse, mutect2, varscan2
- OR4K14 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100520504, COSV59292907; called by muse, mutect2
- OR4X2 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56583403; called by muse, mutect2, varscan2
- OR51L1 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV58624743, COSV58625749; called by muse, mutect2, varscan2
- OR52A5 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223586101, COSV56615321; called by muse, mutect2, varscan2
- OR56A3 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV61569151; called by muse, mutect2, varscan2
- OR56B4 | c.198C>A p.Y66* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs368988213; called by muse, mutect2, varscan2
- OR56B4 | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57204603; called by muse, mutect2, varscan2
- OR5B12 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV56905083; called by muse, mutect2, varscan2
- OR5D13 | c.208T>A p.L70M | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs773654805, COSV62333797; called by muse, mutect2, varscan2
- OR5K3 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.837); catalogued as COSV67349725, COSV67350008; called by muse, mutect2, varscan2
- OR5L1 | c.636G>C p.M212I | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV61732697, COSV61733111, COSV61733957; called by muse, mutect2, varscan2
- OR6Y1 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56928550; called by muse, mutect2, varscan2
- OR8B12 | c.164A>T p.H55L | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV60911760; called by muse, mutect2, varscan2
- OR8I2 | c.809del p.A270Gfs*15 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as COSV56166494, COSV56170718; called by mutect2, pindel, varscan2
- OR8K1 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV54402220, COSV54402616; called by muse, mutect2, varscan2
- ORAI2 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1340787777, COSV62689648; called by muse, mutect2, varscan2
- OTOA | c.1712G>T p.R571M (on ENST00000286149; = p.R557M on NM_144672.4) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.641); catalogued as COSV53754741; called by muse, mutect2, varscan2
- P2RX1 | c.59G>C p.R20P | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56653927; called by muse, mutect2, varscan2
- P2RY14 | c.899A>T p.Q300L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV56379577; called by muse, mutect2, varscan2
- PADI6 | c.1403C>A p.P468Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61884744; called by muse, mutect2, varscan2
- PARP12 | c.479A>T p.N160I | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54934316; called by muse, mutect2, varscan2
- PATE1 | c.334A>T p.N112Y | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV59824581; called by muse, mutect2, varscan2
- PAX4 | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58388945; called by muse, mutect2, varscan2
- PBRM1 | c.1868A>G p.K623R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV56277389; called by muse, mutect2, varscan2
- PBX1 | c.695A>T p.D232V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63343769; called by muse, mutect2, varscan2
- PCDH10 | c.3011G>T p.G1004V | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52094440; called by muse, mutect2, varscan2
- PCDH7 | c.1515C>G p.I505M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62339213, COSV62343153; called by muse, mutect2, varscan2
- PCDHA11 | c.769A>G p.K257E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV56503176; called by muse, mutect2, varscan2
- PCDHB14 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV53388509; called by muse, mutect2, varscan2
- PCK1 | c.298A>G p.R100G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV60128112; called by muse, mutect2, varscan2
- PCLO | c.13167G>T p.R4389S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100426555, COSV61677226; called by muse, mutect2, varscan2
- PCLO | c.13166G>T p.R4389M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100426558; called by muse, mutect2, varscan2
- PCLO | c.4410G>C p.E1470D | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs758585139, COSV61636337; called by muse, mutect2, varscan2
- PDE1A | c.1202C>A p.P401Q | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV59523539; called by muse, mutect2, varscan2
- PDE3A | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV62973221; called by muse, mutect2, varscan2
- PDE3A | c.1701C>A p.Y567* | Nonsense Mutation (SNP) | VAF 101/243 reads (42%) | catalogued as COSV100761740, COSV62973229, COSV62983231; called by muse, mutect2, varscan2
- PDE4DIP | c.5590A>G p.I1864V | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV57696943; called by muse, mutect2, varscan2
- PDPR | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV55352035; called by muse, mutect2, varscan2
- PEX5L | c.287G>T p.R96M | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as rs1016562247, COSV55846385; called by muse, mutect2, varscan2
- PHC2 | c.1671T>A p.N557K (on ENST00000257118 / NM_198040.2; = p.N22K on NM_004427.4) | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV57104012; called by muse, mutect2, varscan2
- PHEX | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV65075721; called by muse, mutect2, varscan2
- PHF14 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV68855432; called by muse, mutect2
- PIK3C2B | c.720G>C p.L240F | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65803657; called by muse, mutect2, varscan2
- PITPNM3 | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV51470916; called by muse, mutect2, varscan2
- PKD1L1 | c.6829G>A p.E2277K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as rs1283510907, COSV56965582; called by muse, mutect2, varscan2
- PKD1L2 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs768499712, COSV100449513; called by muse, mutect2, varscan2
- PKHD1 | c.6205G>T p.D2069Y | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61885374; called by muse, mutect2, varscan2
- PKHD1 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV61876373; called by muse, mutect2, varscan2
- PLA2G4E | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV68150262; called by muse, mutect2, varscan2
- PLA2R1 | c.3599A>T p.D1200V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51778862; called by muse, mutect2, varscan2
- PLCH2 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as COSV53943190; called by muse, varscan2
- PLCZ1 | c.744A>T p.L248F | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56852986, COSV99856173; called by muse, mutect2, varscan2
- PLG | c.1887G>C p.R629S | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.358); catalogued as COSV57516297; called by muse, varscan2
- PLG | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57516306, COSV57521797; called by muse, varscan2
- PLXNA4 | c.704C>A p.T235N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as COSV58111978, COSV58127513; called by muse, mutect2, varscan2
- PMEPA1 | c.605T>G p.L202R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV55693689; called by muse, mutect2, varscan2
- PNN | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as COSV53766587; called by muse, mutect2
- POFUT2 | c.1126G>C p.A376P | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV57959078, COSV57961369; called by muse, mutect2, varscan2
- POLE | c.5251G>T p.A1751S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.11); catalogued as COSV57680721; called by muse, mutect2, varscan2
- POLR3E | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV55400785; called by muse, mutect2, varscan2
- POLR3K | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV53452833; called by muse, mutect2
- PPP1R3A | c.1652G>T p.S551I | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV52882987; called by muse, mutect2, varscan2
- PPP6R3 | c.2327G>C p.S776T (on ENST00000393800 / NM_001352375.2; = p.S696T on NM_018312.5) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55726911; called by muse, mutect2, varscan2
- PREX1 | c.2650G>T p.A884S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV64252019, COSV64258813; called by muse, mutect2, varscan2
- PREX1 | c.2009C>A p.S670Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV64249798, COSV64252026; called by muse, mutect2, varscan2
- PRMT3 | c.772-1G>T p.X258_splice | Splice Site (SNP) | VAF 29/96 reads (30%) | catalogued as COSV58177239; called by muse, mutect2, varscan2
- PRND | c.40T>A p.C14S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV59896555; called by muse, mutect2, varscan2
- PROS1 | c.1429G>T p.V477F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV67775412; called by muse, mutect2, varscan2
- PROX1 | c.1874G>T p.S625I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54779247; called by muse, mutect2, varscan2
- PRPF18 | c.974G>A p.C325Y | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV66074632; called by muse, mutect2, varscan2
- PRSS1 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs545007137, COSV61193202; called by muse, mutect2, varscan2
- PRUNE2 | c.7789A>T p.T2597S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV65041738; called by muse, mutect2, varscan2
- PRUNE2 | c.2090G>C p.R697T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65041746, COSV65041956; called by muse, mutect2, varscan2
- PSAPL1 | c.1096T>A p.C366S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59843178; called by muse, mutect2, varscan2
- PTCH2 | c.2584G>T p.V862L | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV64711120; called by muse, mutect2
- PTPRB | c.384T>A p.H128Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.491); catalogued as COSV51732947; called by muse, mutect2, varscan2
- PTPRG | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV55642031; called by muse, mutect2, varscan2
- PTPRR | c.1331G>T p.S444I | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51732958; called by muse, varscan2
- PUS7 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs141658791, COSV62676779; called by muse, mutect2, varscan2
- PXMP2 | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV58095347; called by muse, mutect2, varscan2
- PXYLP1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs369623029; called by muse, mutect2, varscan2
- R3HDM2 | c.1770G>T p.R590S | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100715073, COSV61288773; called by muse, mutect2
- RAB11FIP1 | c.2587G>T p.E863* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV54760219; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1099A>C p.K367Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV57929205; called by muse, mutect2
- RABGAP1L | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV52296384; called by muse, mutect2, varscan2
- RAMP1 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV54538192; called by mutect2, varscan2
- RASEF | c.1510G>T p.G504W | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV64587168; called by muse, mutect2, varscan2
- RASGEF1C | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV63180733; called by muse, mutect2, varscan2
- RASSF9 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63433710; called by muse, mutect2, varscan2
- RBPMS2 | c.306G>T p.R102S | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55604502; called by muse, mutect2, varscan2
- REG1B | c.191G>T p.C64F | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59305779, COSV59305978; called by muse, mutect2, varscan2
- RGS20 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV52017113; called by muse, mutect2, varscan2
- RHOG | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV53465337; called by muse, mutect2
- RIMS2 | c.2458C>A p.Q820K (on ENST00000666250 / NM_001348490.2; = p.Q628K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51683094; called by muse, mutect2, varscan2
- ROBO3 | c.2221C>A p.Q741K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV101184864; called by muse, varscan2
- ROR2 | c.2357A>G p.Y786C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775209555, COSV65219293; called by muse, mutect2, varscan2
- ROS1 | c.4120A>T p.I1374F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV63852045; called by muse, mutect2, varscan2
- RP1L1 | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66755266; called by muse, mutect2, varscan2
- RPL10L | c.432C>A p.N144K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs1464110614, COSV53559837; called by muse, mutect2, varscan2
- RPS16 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52240073; called by muse, varscan2
- RPS16 | c.345T>A p.Y115* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as COSV52239223, COSV99261740; called by muse, varscan2
- RPS16 | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.4); catalogued as COSV99261742; called by muse, varscan2
- RPS6KA3 | c.453G>T p.R151S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.812); catalogued as COSV65387891; called by muse, mutect2, varscan2
- RPS6KA5 | c.2249G>T p.S750I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV56222107; called by muse, mutect2, varscan2
- RTL3 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV58184201; called by muse, mutect2, varscan2
- RTL5 | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.024); catalogued as rs1258884141, COSV65453523; called by muse, mutect2
- RUBCNL | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV59788620; called by muse, mutect2, varscan2
- RUFY4 | c.1490T>C p.L497S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV60247629; called by muse, mutect2, varscan2
- RYR2 | c.575T>A p.L192* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63686757; called by muse, varscan2
- RYR2 | c.3743C>A p.T1248N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV100767309; called by muse, mutect2, varscan2
- RYR2 | c.6517G>T p.E2173* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV63686773; called by muse, mutect2, varscan2
- SAMD9 | c.4241A>T p.Q1414L | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV66075321, COSV66077164; called by muse, mutect2, varscan2
- SAMD9 | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1462029800, COSV66075328; called by muse, mutect2, varscan2
- SAP130 | c.2592G>C p.K864N | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV52097406; called by muse, mutect2
- SBNO1 | c.2914G>T p.D972Y (on ENST00000420886; = p.D971Y on NM_018183.5) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57341697, COSV57341845; called by muse, varscan2
- SCN2A | c.3865T>A p.L1289I | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51841965; called by muse, mutect2, varscan2
- SCN2A | c.5803G>T p.D1935Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV51841981; called by muse, mutect2, varscan2
- SCNN1A | c.1438A>T p.S480C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV57435706; called by muse, mutect2, varscan2
- SDK1 | c.2670G>C p.W890C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101268837, COSV67361950, COSV67369327; called by muse, mutect2, varscan2
- SEMA5A | c.3157C>A p.P1053T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66793691; called by mutect2, varscan2
- SEMA5A | c.2300-1G>T p.X767_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV66793695; called by mutect2, varscan2
- SEMA7A | c.1659G>C p.K553N | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.345); catalogued as rs1263457633, COSV56090634; called by muse, mutect2, varscan2
- SEPTIN1 | c.1144G>C p.E382Q (on ENST00000321367; = p.E335Q on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.631); catalogued as rs766212898, COSV58442358; called by muse, mutect2, varscan2
- SERPINA10 | c.465C>A p.N155K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56228325; called by muse, mutect2
- SESTD1 | c.1666A>T p.R556W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58931345, COSV58931608; called by muse, mutect2
- SETDB2 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV51644686; called by muse, mutect2, varscan2
- SETX | c.6503G>T p.R2168L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV56385733, COSV56391198; called by muse, mutect2, varscan2
- SF3A1 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV53168967; called by muse, mutect2, varscan2
- SF3B2 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.994); catalogued as COSV59428271; called by muse, mutect2
- SFMBT2 | c.2186A>G p.D729G | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs922102706, COSV62809813; called by muse, mutect2
- SFTPB | c.393+1G>T p.X131_splice | Splice Site (SNP) | VAF 19/56 reads (34%) | catalogued as COSV60893340; called by muse, mutect2, varscan2
- SH3TC2 | c.3200T>A p.L1067Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV60463481; called by muse, mutect2, varscan2
- SHISA3 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.968); catalogued as COSV59979938; called by muse, mutect2, varscan2
- SHOC1 | c.1769A>T p.Q590L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59501537; called by muse, mutect2
- SHROOM2 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV66606844; called by muse, mutect2, varscan2
- SHROOM3 | c.5452G>T p.V1818L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56029531; called by muse, mutect2, varscan2
- SI | c.4283C>A p.T1428N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52265399; called by muse, mutect2, varscan2
- SI | c.444C>A p.F148L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100017700, COSV52279571; called by muse, mutect2, varscan2
- SIGLEC10 | c.205A>G p.K69E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV59481962; called by muse, mutect2, varscan2
- SIPA1L1 | c.4759G>T p.E1587* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV62170333; called by muse, mutect2, varscan2
- SLC12A9 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51933594; called by muse, mutect2, varscan2
- SLC19A3 | c.1039C>G p.L347V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV51452854; called by muse, mutect2, varscan2
- SLC22A7 | c.1498G>T p.G500W (on ENST00000372585 / NM_153320.2; = p.G498W on NM_006672.3) | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as rs761964882, COSV51484050; called by muse, mutect2, varscan2
- SLC25A36 | c.394G>C p.A132P | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60782013; called by muse, mutect2, varscan2
- SLC29A4 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV51874344; called by muse, mutect2, varscan2
- SLC44A5 | c.2095G>T p.V699L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV63764377, COSV63765257; called by muse, mutect2, varscan2
- SLC8A1 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV60481154, COSV60482169; called by muse, mutect2, varscan2
- SLC9A4 | c.442A>C p.T148P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV54833981; called by muse, mutect2, varscan2
- SLC9A9 | c.1879G>T p.G627C | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57227759; called by muse, mutect2, varscan2
- SLIT2 | c.1304A>T p.D435V | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56573213; called by muse, mutect2, varscan2
- SLITRK3 | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53848663; called by muse, mutect2, varscan2
- SLITRK4 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62024000, COSV62025364; called by muse, mutect2, varscan2
- SMG6 | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53967414; called by muse, mutect2, varscan2
- SNX1 | c.1283A>T p.Q428L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV56038365; called by muse, mutect2, varscan2
- SNX14 | c.1771G>A p.V591M (on ENST00000314673 / NM_001350535.1; = p.V538M on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59012119; called by muse, mutect2, varscan2
- SORCS1 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV53867683, COSV53913322; called by muse, mutect2, varscan2
- SORL1 | c.6517G>T p.A2173S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99492628; called by muse, mutect2, varscan2
- SOX1 | c.51G>C p.Q17H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as rs754715087, COSV58379084; called by muse, mutect2, varscan2
- SPAG17 | c.2810T>A p.L937H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60459254; called by muse, mutect2
- SPATA31D1 | c.4508A>T p.E1503V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV61196070; called by muse, mutect2, varscan2
- SPTA1 | c.6544G>T p.D2182Y | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV63753555; called by muse, mutect2, varscan2
- SRGAP3 | c.1938C>A p.D646E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.591); catalogued as COSV64533496; called by muse, mutect2, varscan2
- SRGAP3 | c.1495T>A p.Y499N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV64533504; called by muse, mutect2, varscan2
- SS18L1 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV59210712; called by muse, mutect2
- ST14 | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53833337; called by muse, mutect2, varscan2
- STAU2 | c.1029G>T p.Q343H (on ENST00000524300 / NM_001164380.2; = p.Q311H on NM_014393.2) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63308331; called by muse, mutect2, varscan2
- STRIP1 | c.883T>A p.L295M | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV63929824; called by muse, mutect2, varscan2
- STYXL2 | c.1541G>T p.R514M | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV54805326; called by muse, mutect2, varscan2
- SUSD5 | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.168); catalogued as COSV58877820; called by muse, mutect2, varscan2
- SVOPL | c.730C>A p.R244S (on ENST00000419765; = p.R92S on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV55991356, COSV99939047; called by muse, mutect2, varscan2
- SYNE1 | c.4402G>T p.E1468* (on ENST00000367255 / NM_182961.4; = p.E1475* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV54986905, COSV55102118; called by muse, mutect2, varscan2
- SYNE2 | c.10609A>T p.S3537C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV59951624; called by muse, mutect2, varscan2
- SYNE3 | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs753066371, COSV62079578; called by muse, mutect2, varscan2
- TAAR8 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759336088, COSV51586315; called by muse, mutect2, varscan2
- TAAR8 | c.298G>T p.G100* | Nonsense Mutation (SNP) | VAF 19/158 reads (12%) | catalogued as COSV51586323; called by muse, mutect2, varscan2
- TAAR9 | c.939C>A p.F313L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV71512238; called by muse, mutect2, varscan2
- TAC1 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV59987484; called by muse, mutect2, varscan2
- TAF1L | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs145899352; called by muse, mutect2, varscan2
- TAF3 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60206790; called by muse, mutect2, varscan2
- TARS1 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV54309277; called by muse, mutect2
- TAS2R30 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV67856115; called by muse, mutect2
- TASOR2 | c.6187C>G p.L2063V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV60167565; called by muse, mutect2
- TATDN3 | c.682-1G>T p.X228_splice | Splice Site (SNP) | VAF 39/155 reads (25%) | catalogued as COSV65325280; called by muse, varscan2
- TCHHL1 | c.2071G>T p.G691* | Nonsense Mutation (SNP) | VAF 34/215 reads (16%) | catalogued as COSV64285797; called by muse, mutect2, varscan2
- TCTE1 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV65255582, COSV65255590; called by muse, mutect2, varscan2
- TENM1 | c.837C>A p.N279K | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV64432374; called by muse, varscan2
- TET3 | c.545G>C p.W182S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV59881042; called by muse, mutect2, varscan2
- TFAP2B | c.157A>T p.S53C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV53827937; called by muse, mutect2
- THBS2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs781551028, COSV64679002; called by muse, mutect2, varscan2
- THSD7B | c.2793T>A p.Y931* | Nonsense Mutation (SNP) | VAF 27/138 reads (20%) | catalogued as COSV55688489; called by muse, mutect2, varscan2
- TIMM44 | c.954G>T p.Q318H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as rs752101441, COSV54491852; called by muse, mutect2, varscan2
- TMEM236 | c.791G>C p.S264T | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1378724059; called by muse, mutect2, varscan2
- TMPRSS11B | c.17T>C p.I6T | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV60292446; called by muse, mutect2
- TMTC1 | c.841C>T p.H281Y (on ENST00000539277 / NM_001193451.2; = p.H173Y on NM_175861.3) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.197); catalogued as COSV55482173; called by muse, mutect2, varscan2
- TNN | c.3166A>T p.T1056S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV53426567; called by muse, mutect2, varscan2
- TNPO3 | c.2306G>T p.R769L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV99602334; called by muse, mutect2, varscan2
- TOMM40L | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs933544110, COSV63468023; called by muse, mutect2, varscan2
- TP53BP1 | c.3235G>T p.G1079C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV55501830; called by muse, mutect2, varscan2
- TPK1 | c.565G>T p.G189* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV63641130; called by muse, mutect2, varscan2
- TPO | c.92G>T p.W31L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV61102201; called by muse, mutect2, varscan2
- TRAT1 | c.290C>A p.T97N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55468665, COSV55469060; called by muse, mutect2, varscan2
- TRIM40 | c.179G>C p.C60S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV57155779, COSV57156634; called by muse, mutect2, varscan2
- TSHZ2 | c.3025G>T p.V1009L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1568839390, COSV61588855; called by muse, mutect2, varscan2
- TSLP | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61291700; called by muse, mutect2, varscan2
- TSNARE1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV56176390; called by muse, mutect2, varscan2
- TTC39A | c.1058A>G p.H353R (on ENST00000447632 / NM_001297665.1; = p.H318R on NM_001080494.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52958156; called by muse, mutect2, varscan2
- TTN | c.50429G>T p.R16810L (on ENST00000591111; = p.R9386L on NM_003319.4) | Missense Mutation (SNP) | VAF 19/120 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV59877034, COSV59932648; called by muse, mutect2, varscan2
- TTN | c.30844del p.E10282Kfs*26 (on ENST00000591111; = p.E9355Kfs*26 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 64/281 reads (23%) | catalogued as COSV59866104; called by mutect2, pindel, varscan2
- TTN | c.17712A>T p.E5904D (on ENST00000591111; = p.E4977D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/131 reads (31%) | PolyPhen benign (0.318); catalogued as COSV60075142; called by muse, mutect2, varscan2
- TTN | c.1493T>A p.V498E | Missense Mutation (SNP) | VAF 12/120 reads (10%) | PolyPhen benign (0); catalogued as COSV60075197; called by muse, mutect2
- TUB | c.1425G>T p.E475D (on ENST00000299506 / NM_177972.3; = p.E530D on NM_003320.4) | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as COSV55108082; called by muse, mutect2, varscan2
- TXNDC16 | c.1579G>T p.V527L | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV55984806; called by muse, mutect2
- UBA6 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV59177412; called by muse, mutect2, varscan2
- UGT1A1 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750232648, COSV59389029, COSV59400861; called by muse, mutect2, varscan2
- UGT2B28 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.189); catalogued as COSV59432177, COSV59434774; called by muse, mutect2, varscan2
- UGT3A2 | c.757T>A p.F253I | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56930690; called by muse, mutect2, varscan2
- USF1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV57037735; called by muse, mutect2, varscan2
- USH2A | c.5891G>T p.R1964L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as rs149465057, COSV56372471; called by muse, mutect2, varscan2
- USH2A | c.2855C>A p.S952* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV56372487; called by muse, mutect2, varscan2
- VCAN | c.2026C>G p.L676V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV54105520; called by muse, mutect2, varscan2
- VIPR2 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV51107214; called by mutect2, varscan2
- VPS13A | c.5203G>A p.A1735T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62430300; called by muse, mutect2, varscan2
- WASHC2C | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.381); catalogued as COSV60491473; called by muse, mutect2, varscan2
- WDR4 | c.431A>C p.H144P | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57733625; called by muse, mutect2, varscan2
- XIRP2 | c.5453G>A p.G1818E (on ENST00000628543; = p.G1993E on NM_152381.6) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs371858271, COSV54701532; called by muse, varscan2
- XIRP2 | c.6284C>G p.S2095C (on ENST00000628543; = p.S2270C on NM_152381.6) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV54701542; called by muse, mutect2, varscan2
- XYLB | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99263920; called by muse, mutect2, varscan2
- ZAN | c.2255C>A p.P752H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61809374; called by muse, mutect2, varscan2
- ZAN | c.3628T>A p.C1210S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.764); catalogued as COSV100769003; called by muse, mutect2, varscan2
- ZBED4 | c.3312G>A p.W1104* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV53465718; called by muse, mutect2, varscan2
- ZBTB24 | c.234G>C p.M78I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV57782108; called by muse, mutect2, varscan2
- ZC3H14 | c.1377G>C p.M459I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV51769693; called by muse, mutect2, varscan2
- ZFP57 | c.701C>A p.T234K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV65306204; called by muse, mutect2, varscan2
- ZFPM2 | c.1553C>A p.A518D | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1409424269, COSV65873760; called by muse, mutect2, varscan2
- ZFYVE1 | c.779C>G p.S260* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100606853, COSV59611243; called by muse, mutect2
- ZKSCAN8 | c.702G>T p.W234C | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs756363905, COSV57636744; called by muse, mutect2, varscan2
- ZNF2 | c.1214C>T p.T405M (on ENST00000611147 / NM_001291605.2; = p.T392M on NM_021088.4) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745767414, COSV54637027; called by muse, mutect2, varscan2
- ZNF223 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs759670869, COSV71571900; called by muse, mutect2, varscan2
- ZNF226 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.533); catalogued as COSV56196641; called by muse, mutect2, varscan2
- ZNF33A | c.1157G>T p.C386F (on ENST00000458705 / NM_006974.3; = p.C387F on NM_006954.2) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765533632, COSV100275443; called by muse, mutect2, varscan2
- ZNF417 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100364348, COSV56308434; called by muse, mutect2, varscan2
- ZNF502 | c.1405G>T p.G469W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56073668; called by muse, mutect2, varscan2
- ZNF521 | c.3115G>T p.G1039W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320205060, COSV64127130; called by muse, mutect2
- ZNF521 | c.3113A>T p.H1038L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64127133; called by muse, mutect2
- ZNF536 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100835263, COSV62824646; called by muse, mutect2, varscan2
- ZNF536 | c.3383G>T p.S1128I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as rs893640530, COSV62824649; called by muse, mutect2, varscan2
- ZNF574 | c.1636A>T p.T546S | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV55903631; called by muse, mutect2, varscan2
- ZNF648 | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.001); catalogued as COSV60571029; called by muse, mutect2, varscan2
- ZNF804A | c.229A>G p.N77D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56449426; called by muse, mutect2, varscan2
- ZNF823 | c.1787G>T p.R596L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV57873844; called by muse, mutect2, varscan2
- ZNF875 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60991392; called by muse, mutect2, varscan2
- ZP4 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.58); catalogued as rs889208920, COSV63912076; called by muse, mutect2, varscan2
- ZSCAN10 | c.59C>A p.P20Q (on ENST00000252463; = p.P75Q on NM_032805.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52967711, COSV52968159; called by muse, mutect2, varscan2
- ZSCAN20 | c.229T>C p.C77R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100792467; called by muse, mutect2
- ZSCAN20 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100792469; called by muse, mutect2
- ZSCAN26 | c.919G>T p.E307* (on ENST00000623276 / NM_001111039.2; = p.E173* on NM_152736.5) | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV52553539; called by muse, mutect2, varscan2
- ZSWIM3 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54847661; called by muse, mutect2, varscan2
- ZZZ3 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66232805; called by muse, mutect2, varscan2
- AATF | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTSL1 | c.5030dup p.C1678Vfs*28 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- ANKRD20A4P | c.1793G>T p.S598I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.193); called by mutect2, varscan2
- BTBD7 | c.1752+1del p.X584_splice | Splice Site (DEL) | VAF 26/108 reads (24%) | called by mutect2, pindel, varscan2
- C6orf118 | c.985del p.A329Rfs*10 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- CDC7 | c.863del p.G288Efs*18 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- CDHR1 | c.2401del p.A801Rfs*40 | Frame Shift Del (DEL) | VAF 31/124 reads (25%) | called by mutect2, pindel, varscan2
- DRD1 | c.1027del p.T343Pfs*3 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- EDNRB | c.502del p.A168Qfs*46 (on ENST00000377211 / NM_001201397.1; = p.A78Qfs*46 on NM_000115.5) | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- GDF3 | c.56del p.G19Afs*17 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- HTR1A | c.238del p.V80Sfs*28 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGHV5-51 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- IGKC | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGKV1-17 | c.142A>G p.S48G | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- IGKV1D-43 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- KCTD8 | c.1208del p.P403Hfs*32 | Frame Shift Del (DEL) | VAF 40/320 reads (13%) | called by mutect2, pindel, varscan2
- LILRB3 | c.1508C>A p.T503K (on ENST00000346401; = p.T491K on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2
- LMO7 | c.1492G>A p.D498N (on ENST00000357063; = p.D228N on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MPHOSPH10 | c.709_711del p.F237del | In Frame Del (DEL) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- MRC1 | c.4069A>G p.R1357G | Missense Mutation (SNP) | VAF 77/235 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- MRPL45 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- MYOF | c.2125A>T p.T709S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2
- NAA16 | c.1410+1dup | Frame Shift Ins (INS) | VAF 30/126 reads (24%) | called by mutect2, pindel, varscan2
- NALCN | c.358del p.V120Ffs*13 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | called by mutect2, pindel, varscan2
- POP1 | c.876del p.V293Cfs*5 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by mutect2, pindel, varscan2
- PRKCH | c.1933del p.D645Tfs*5 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | called by mutect2, pindel, varscan2
- RIF1 | c.1149dup p.V384Cfs*50 | Frame Shift Ins (INS) | VAF 37/180 reads (21%) | called by mutect2, pindel, varscan2
- SCN8A | c.879dup p.E294* | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- SERPINB11 | c.1176del p.*393Nfs*13 | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- SIM1 | c.2257del p.Q753Kfs*9 | Frame Shift Del (DEL) | VAF 26/141 reads (18%) | called by mutect2, pindel, varscan2
- SORL1 | c.2849del p.G950Afs*58 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | called by mutect2, pindel, varscan2
- SPEF2 | c.2813dup p.T939Yfs*14 | Frame Shift Ins (INS) | VAF 15/132 reads (11%) | called by mutect2, pindel, varscan2
- SSX2 | c.479G>A p.G160E (on ENST00000337502 / NM_175698.2; = p.G209R on NM_003147.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/355 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.284); called by mutect2, varscan2
- TPTE | c.895G>T p.V299F (on ENST00000618007 / NM_199261.4; = p.V281F on NM_199259.4) | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- WDR75 | c.2424del p.L808Ffs*9 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- ZAN | c.2254C>A p.P752T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF835 | c.272dup p.E92Gfs*5 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- AADAT | c.30G>C p.A10= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as rs755262373, COSV61787240; called by muse, mutect2, varscan2
- ABCA13 | c.6168A>G p.E2056= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV70029584; called by muse, mutect2, varscan2
- ABCC3 | c.228G>T p.L76= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV53322058; called by muse, mutect2, varscan2
- ADAMTS12 | c.3906C>A p.A1302= | Silent (SNP) | VAF 48/317 reads (15%) | catalogued as rs374664813; called by muse, mutect2, varscan2
- ADAMTS7 | c.4953A>T p.L1651= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV66307346; called by muse, mutect2, varscan2
- ADCY8 | c.1152G>T p.L384= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV53908395, COSV53927461; called by muse, mutect2, varscan2
- ADGRB3 | c.3453G>T p.R1151= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV53245454; called by muse, varscan2
- ADGRF2 | c.327C>T p.C109= (on ENST00000296862 / NM_001368115.2; = p.C41= on NM_153839.7) | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs780268361, COSV57288427; called by muse, mutect2, varscan2
- ADGRV1 | c.4053A>G p.T1351= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV67978981; called by mutect2, varscan2
- AGO1 | c.12A>T p.G4= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV64595352; called by muse, mutect2, varscan2
- AGRN | c.2106G>T p.P702= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV65069692; called by muse, mutect2, varscan2
- AIPL1 | c.696G>T p.L232= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100006073, COSV51507156; called by muse, mutect2, varscan2
- AKR7A3 | c.744G>A p.V248= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1209607762, COSV64389264; called by muse, mutect2, varscan2
198 further variants in this file (0 protein-altering or splice-affecting, 174 silent, 24 other) are not listed here.
